Somatic mutation profile of tumor specimen ALCH-B1UI-TTP1-A (aliquot ALCH-B1UI-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1UI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Mixed invasive mucinous and non-mucinous adenocarcinoma; Age at diagnosis: 63.8 years (23,285 days).
Specimen ALCH-B1UI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f11e47ab-8b15-4fbb-9d8a-726a337b2106.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1UI-NB1-A (Blood Derived Normal), aliquot ALCH-B1UI-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db0dc17b-97e7-45fd-a979-73fb1a3b26d0

The open-access MAF lists 42 somatic variants for this specimen: 34 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 5'UTR 3, Silent 2, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1, Splice Region 1, 5'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 33/185 reads (18%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- IFT140 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417500285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 50/244 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 36/168 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2, varscan2
- CD276 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 84/444 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs561421890; called by muse, mutect2, varscan2
- DUSP4 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1004262894; called by muse, mutect2, varscan2
- FNTA | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs749982034; called by muse, mutect2, varscan2
- GALNTL5 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601426, COSV101217812; called by muse, mutect2, varscan2
- GOLGA8J | c.1309del p.E437Rfs*20 | Frame Shift Del (DEL) | VAF 55/526 reads (10%) | catalogued as rs761109952; called by mutect2, pindel, varscan2
- KIR3DL1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 61/508 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs375468097; called by muse, mutect2, varscan2
- LRFN5 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53258144; called by muse, mutect2, varscan2
- PCDH11X | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.963); catalogued as COSV100011043; called by muse, mutect2, varscan2
- PCDHB8 | c.1373C>A p.T458N | Missense Mutation (SNP) | VAF 108/1472 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); catalogued as rs782596972, COSV50780408; called by muse, mutect2
- TSHZ3 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1270874522, COSV53663245, COSV53670748; called by muse, mutect2, varscan2
- UBE2R2 | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363142234, COSV99602353; called by muse, mutect2, varscan2
- USP42 | c.3269A>T p.E1090V | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs1344071894; called by muse, mutect2
- ZER1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.563); catalogued as rs764346710; called by muse, mutect2, varscan2
- AKAP1 | c.1932_1943del p.L646_T649del | In Frame Del (DEL) | VAF 24/226 reads (11%) | called by mutect2, pindel
- ALG13 | c.935G>C p.R312P | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C16orf82 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CLRN1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, varscan2
- CRACD | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH9 | c.5245T>A p.Y1749N | Missense Mutation (SNP) | VAF 87/493 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DOP1A | c.3292C>T p.L1098F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- HELZ2 | c.2581A>G p.I861V (on ENST00000467148 / NM_001037335.2; = p.I292V on NM_033405.3) | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KCNF1 | c.1369_1411del p.A457Pfs*10 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- MATN1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NKX2-1 | c.841dup p.S281Kfs*128 | Frame Shift Ins (INS) | VAF 36/175 reads (21%) | called by mutect2, pindel, varscan2
- OTOGL | c.5099C>G p.T1700R (on ENST00000547103; = p.T1691R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PNPLA6 | c.2264A>G p.Q755R (on ENST00000414982 / NM_001166111.2; = p.Q707R on NM_006702.5) | Missense Mutation (SNP) | VAF 95/481 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- POM121C | c.3672G>T p.Q1224H (on ENST00000607367; = p.Q982H on NM_001099415.3) | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STYXL2 | c.1938G>A p.W646* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- TSPAN3 | c.672G>T p.L224= | Splice Region (SNP) | VAF 43/219 reads (20%) | called by muse, mutect2, varscan2
- ZNF501 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MATN1 | c.1335G>A p.K445= | Silent (SNP) | VAF 32/206 reads (16%) | catalogued as rs780510349; called by muse, varscan2
- PXDN | c.1803G>C p.G601= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2
- CISD1 | c.-62C>T | 5'UTR (SNP) | VAF 72/342 reads (21%) | called by muse, mutect2, varscan2
- GTF2H2B | n.748C>G | RNA (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- KRT17 | c.*37G>A | 3'UTR (SNP) | VAF 38/178 reads (21%) | called by muse, mutect2, varscan2
- NPS | c.-35A>T | 5'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77917075 G>A | 5'Flank (SNP) | VAF 90/526 reads (17%) | called by muse, varscan2
- SYNPR | c.-8G>A | 5'UTR (SNP) | VAF 14/81 reads (17%) | catalogued as rs1376623980; called by muse, mutect2, varscan2
